Somatic mutation profile of tumor specimen TCGA-24-1847-01A (aliquot TCGA-24-1847-01A-01W-0633-09) from TCGA case TCGA-24-1847, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.3 years (16,529 days).
Specimen TCGA-24-1847-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8141c80-922e-4363-a4f7-42a9e7ed71d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1847-10A (Blood Derived Normal), aliquot TCGA-24-1847-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17f8a807-0607-4418-8f61-f87f5abc5033

The open-access MAF lists 114 somatic variants for this specimen: 85 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 28, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, In Frame Del 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 53/114 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.2503C>A p.L835I | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV59393149; called by muse, mutect2, varscan2
- ABLIM3 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58649433; called by muse, mutect2, varscan2
- ACSM2B | c.776C>A p.T259N | Missense Mutation (SNP) | VAF 97/462 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100312698; called by muse, mutect2, varscan2
- ALAS2 | c.1426A>T p.I476F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100238356; called by muse, mutect2
- ARHGAP31 | c.2781C>G p.H927Q | Missense Mutation (SNP) | VAF 46/574 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1299800217, COSV99957157; called by muse, mutect2
- ATAD2 | c.3949G>A p.A1317T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99784729; called by muse, mutect2
- BCAN | c.1106C>G p.A369G | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61260019; called by muse, mutect2, varscan2
- BOD1L1 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 25/148 reads (17%) | catalogued as COSV50080738; called by muse, mutect2, varscan2
- BRCA1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 60/115 reads (52%) | catalogued as CD140256, COSV58783769, COSV58801512; called by muse, mutect2, varscan2
- BRD8 | c.2092G>T p.V698F (on ENST00000254900 / NM_139199.2; = p.V771F on NM_006696.4) | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV50172626; called by muse, mutect2, varscan2
- CABS1 | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV56734748; called by muse, mutect2, varscan2
- CCDC70 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54431132; called by muse, mutect2, varscan2
- CCIN | c.417G>T p.L139F | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58725881; called by muse, mutect2, varscan2
- CEBPE | c.599T>G p.V200G | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV52830861; called by muse, mutect2, varscan2
- CELSR2 | c.647_648del p.L216Rfs*9 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | catalogued as COSV54780247; called by mutect2, varscan2
- CNTNAP3 | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV99904844; called by muse, mutect2, varscan2
- CTNND2 | c.379T>A p.C127S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.942); catalogued as COSV58932834; called by muse, mutect2, varscan2
- CTSL | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 119/194 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.273); catalogued as COSV58247770; called by muse, mutect2, varscan2
- CYP11A1 | c.1469T>A p.L490H | Missense Mutation (SNP) | VAF 65/209 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV51435226; called by muse, mutect2, varscan2
- CYP4F22 | c.279C>A p.H93Q | Missense Mutation (SNP) | VAF 96/276 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54112358; called by muse, mutect2, varscan2
- DBH | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs759245407, COSV55042546; called by muse, mutect2, varscan2
- DCLK1 | c.199C>G p.R67G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55193218, COSV99711320, COSV99712147; called by muse, mutect2
- DDX58 | c.2494A>G p.T832A | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs567033543, COSV100008153; called by mutect2, varscan2
- DNAH11 | c.7747G>A p.V2583M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV60985307; called by muse, varscan2
- DST | c.5827G>C p.E1943Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as COSV55043970; called by muse, mutect2, varscan2
- EFCAB13 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58953336; called by muse, mutect2, varscan2
- FAM186B | c.689T>A p.V230D | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV57724248, COSV99218586; called by muse, mutect2, varscan2
- FAT4 | c.12922A>T p.T4308S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV58711783; called by muse, mutect2, varscan2
- FBH1 | c.490C>T p.Q164* (on ENST00000362091 / NM_178150.3; = p.Q215* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV62984739; called by muse, mutect2, varscan2
- GOLGB1 | c.3902G>T p.G1301V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV61471943; called by muse, mutect2, varscan2
- GPAM | c.2113T>A p.Y705N | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV62082831; called by muse, mutect2, varscan2
- GSTM5 | c.457-1G>T p.X153_splice | Splice Site (SNP) | VAF 30/283 reads (11%) | catalogued as COSV56657036, COSV56657991; called by muse, mutect2, varscan2
- INTS9 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV68436062; called by muse, mutect2, varscan2
- ISM2 | c.1643A>T p.N548I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99376657; called by muse, mutect2, varscan2
- ITSN1 | c.472dup p.L158Pfs*3 | Frame Shift Ins (INS) | VAF 12/83 reads (14%) | catalogued as rs751926247; called by mutect2, varscan2
- KANK1 | c.2782G>C p.E928Q | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.051); catalogued as COSV63216717; called by muse, mutect2, varscan2
- KATNAL2 | c.455T>C p.V152A (on ENST00000356157 / NM_001353899.1; = p.V80A on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/304 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs370114578; called by muse, mutect2
- KCNJ15 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100154214; called by muse, mutect2
- KCNMB3 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV100046594, COSV58571743; called by muse, mutect2, varscan2
- KIF5A | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54059749; called by muse, mutect2, varscan2
- KRT2 | c.1511C>A p.T504K | Missense Mutation (SNP) | VAF 109/837 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV59012994; called by muse, mutect2, varscan2
- LCE1D | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | PolyPhen possibly damaging (0.877); catalogued as rs1278979424, COSV58271407, COSV58271891; called by muse, mutect2, varscan2
- MAGEA8 | c.416T>A p.L139H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99674611; called by muse, mutect2
- MAML1 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.083); catalogued as COSV99483124; called by muse, mutect2
- MOAP1 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52093971; called by muse, mutect2, varscan2
- MTCL1 | c.3038C>G p.T1013S (on ENST00000306329 / NM_001378206.1; = p.T694S on NM_015210.4) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV60412685; called by muse, mutect2, varscan2
- MUC16 | c.24215C>A p.S8072Y | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV101200000, COSV67460728; called by muse, mutect2, varscan2
- MUC17 | c.3233A>T p.Q1078L | Missense Mutation (SNP) | VAF 80/523 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV60305992; called by muse, mutect2, varscan2
- MYOC | c.1397C>A p.P466Q | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99231513; called by muse, mutect2
- NEK1 | c.3224A>G p.D1075G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV71458252; called by muse, mutect2, varscan2
- NPTX2 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99674918; called by muse, mutect2
- PAFAH2 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs902766750, COSV100959270; called by muse, mutect2
- PDYN | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54103666; called by muse, mutect2, varscan2
- PIP | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV52121875; called by muse, mutect2, varscan2
- POF1B | c.1723C>A p.Q575K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV99426745; called by muse, mutect2, varscan2
- POP1 | c.1842G>T p.W614C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100855865; called by muse, mutect2
- PRPF40A | c.1372A>G p.M458V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV62961040; called by muse, mutect2, varscan2
- PSME4 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66368214; called by muse, mutect2, varscan2
- RALGAPA2 | c.4949C>T p.A1650V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52513102; called by muse, mutect2, varscan2
- RGS9 | c.1385C>A p.A462D | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52229859; called by muse, mutect2, varscan2
- RNF130 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56154389; called by muse, mutect2, varscan2
- RPA2 | c.77dup p.F27Lfs*35 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | catalogued as rs771264048; called by pindel, varscan2
- SEC23B | c.2230A>C p.I744L | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52724386; called by muse, mutect2, varscan2
- SEMG2 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); catalogued as COSV65647222, COSV65648051; called by muse, mutect2, varscan2
- SHROOM3 | c.5436C>A p.N1812K | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99934409, COSV99935800; called by muse, mutect2
- SHROOM4 | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV56798194; called by muse, mutect2, varscan2
- SLCO1C1 | c.1881A>T p.R627S | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV56881126; called by muse, mutect2, varscan2
- SNX18 | c.1470C>A p.N490K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV100410449; called by muse, mutect2, varscan2
- SNX18 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.084); catalogued as COSV100410450; called by muse, mutect2, varscan2
- SPARC | c.23T>A p.L8H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.362); catalogued as COSV50558823; called by muse, mutect2
- SPRED2 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as COSV62696277; called by muse, mutect2, varscan2
- SRPX | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100656081; called by muse, mutect2
- TARBP1 | c.3503T>C p.V1168A | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV50210427; called by muse, mutect2, varscan2
- TENM2 | c.2942A>T p.H981L (on ENST00000518659 / NM_001122679.2; = p.H749L on NM_001080428.3) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs752488147, COSV69143507; called by muse, mutect2, varscan2
- TMPRSS5 | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100244631; called by muse, mutect2
- TSPAN16 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as COSV57443743; called by mutect2, varscan2
- USH2A | c.5005T>C p.F1669L | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); catalogued as COSV100235222; called by muse, mutect2
- USP29 | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54140777, COSV54146314, COSV54147218; called by muse, mutect2, varscan2
- VAV3 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs372445365, COSV64072820; called by muse, mutect2, varscan2
- VWF | c.5779T>A p.C1927S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM930738, COSV54636461; called by muse, mutect2, varscan2
- ZSCAN22 | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61639711; called by muse, mutect2, varscan2
- FAM186B | c.814_861del p.L272_E287del | In Frame Del (DEL) | VAF 144/587 reads (25%) | called by mutect2, pindel
- GPRC5B | c.364_372del p.C122_V124del | In Frame Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- TRRAP | c.1037-30_1053del p.X346_splice | Splice Site (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- ADNP2 | c.1170C>T p.L390= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as rs1568415680, COSV51542807; called by muse, mutect2
- ATXN7L3 | c.138C>G p.G46= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV66989786; called by muse, mutect2, varscan2
- CD84 | c.723T>C p.S241= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100246017; called by muse, mutect2, varscan2
- CLNK | c.1116G>A p.L372= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV99905237; called by muse, mutect2, varscan2
- COL5A3 | c.1650T>G p.R550= | Silent (SNP) | VAF 81/299 reads (27%) | catalogued as COSV53420374; called by muse, mutect2, varscan2
- DNAJC22 | c.999C>T p.P333= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1431162707, COSV67713028; called by muse, mutect2, varscan2
- DTX3 | c.339G>A p.E113= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV54091187; called by muse, mutect2, varscan2
- ERBIN | c.1353G>A p.E451= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs948655410, COSV99396894; called by muse, mutect2
- FAM199X | c.816C>T p.T272= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV100245547; called by muse, mutect2
- FAM47A | c.1596G>A p.P532= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs372096171, COSV60500215; called by muse, mutect2, varscan2
- GPR162 | c.633G>C p.R211= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99163779; called by muse, mutect2, varscan2
- GPR162 | c.634A>C p.R212= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99163780; called by muse, mutect2, varscan2
- GPR31 | c.93C>A p.G31= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100834136; called by muse, mutect2
- GZMB | c.459G>A p.L153= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99362351; called by muse, mutect2
- KMO | c.1356C>A p.R452= | Silent (SNP) | VAF 67/203 reads (33%) | catalogued as COSV59367768; called by muse, mutect2, varscan2
- LMOD3 | c.147C>G p.P49= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV101342017, COSV70456835; called by muse, mutect2, varscan2
- MAGEB4 | c.894T>C p.N298= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV66776748; called by muse, mutect2, varscan2
- MAGEC1 | c.3276G>A p.K1092= | Silent (SNP) | VAF 100/414 reads (24%) | catalogued as COSV53570964, COSV53573276; called by muse, mutect2, varscan2
- MARF1 | c.4590C>T p.H1530= | Silent (SNP) | VAF 44/240 reads (18%) | catalogued as rs1163438902, COSV60030046; called by muse, mutect2, varscan2
- MIGA2 | c.201G>A p.R67= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99477631; called by muse, mutect2
- MTG2 | c.843C>T p.G281= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs777639547, COSV63695012; called by muse, mutect2, varscan2
- NFS1 | c.933A>C p.A311= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV65054444; called by muse, mutect2, varscan2
- NRXN3 | c.126C>T p.S42= | Silent (SNP) | VAF 76/322 reads (24%) | catalogued as COSV55359774; called by muse, mutect2, varscan2
- PTCHD4 | c.618G>A p.Q206= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV59798890; called by muse, mutect2, varscan2
- RGL3 | c.289C>T p.L97= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100710538; called by muse, mutect2
- RYR1 | c.11520C>A p.V3840= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100615798; called by muse, mutect2
- ZFPM2 | c.933A>C p.R311= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as COSV65876390; called by muse, mutect2, varscan2
- ZNF287 | c.546G>A p.E182= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV101209383; called by muse, mutect2
- VPS26C | chr21:37221406 A>G | 3'Flank (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
